Gene-level copy-number profile of tumor specimen MP2PRT-PARPVK-TMP1-A from MP2PRT case MP2PRT-PARPVK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,855 days).
Specimen MP2PRT-PARPVK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df40f920-59b1-47d3-8d29-55fc28a434d0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARPVK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/72da1251-3215-470d-91bd-a5293087ce10

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 5; copy number 2: 38,153; copy number 3: 1,145; copy number 4: 1,715; copy number 5: 2,260; copy number 6: 12,597; copy number 8: 119; copy number 9: 14; copy number 10: 2,342.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,988 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,562,149, 716 genes, copy number 6 (broad region; genes not listed).
- chr4:51,843,000–190,092,279, 1,850 genes, copy number 6 (broad region; genes not listed).
- chr6:105,919–170,738,536, 2,961 genes, copy number 5–6 (broad region; genes not listed).
- chr10:14,061–30,403,776, 496 genes, copy number 5 (broad region; genes not listed).
- chr10:30,517,616–38,783,108, 148 genes, copy number 5 (broad region; genes not listed).
- chr10:42,475,480–133,778,699, 1,608 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–106,425,654, 2,170 genes, copy number 6–8 (within-gene range 0–8) (broad region; genes not listed).
- chr14:106,463,256–106,463,691, 1 gene, copy number 6 (within-gene range 1–6): IGHV3-42.
- chr14:106,472,791–106,879,812, 63 genes, copy number 6 (broad region; genes not listed).
- chr17:142,789–83,240,804, 3,020 genes, copy number 6–9 (broad region; genes not listed).
- chr18:45,034–80,247,514, 1,199 genes, copy number 6 (broad region; genes not listed).
- chr21:7,744,962–9,129,752, 42 genes, copy number 6: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:13,443,373–46,691,226, 714 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
